Somatic mutation profile of tumor specimen TARGET-30-PASKFV-01A (aliquot TARGET-30-PASKFV-01A-01D) from TARGET case TARGET-30-PASKFV, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.7 years (992 days).
Specimen TARGET-30-PASKFV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0e03dd3-3d64-4abb-b51a-18cf869c239d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASKFV-10A (Blood Derived Normal), aliquot TARGET-30-PASKFV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bd41eeb-f1f2-471c-864c-3c3bea93ae52

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLEC10A | c.503C>A p.A168D (on ENST00000254868 / NM_182906.4; = p.A141D on NM_006344.4) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV54700289; called by muse, mutect2, varscan2
- CHD6 | c.3477C>T p.I1159= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs766920320, COSV58554103; called by muse, mutect2, varscan2
